Somatic mutation profile of tumor specimen TCGA-24-1423-01A (aliquot TCGA-24-1423-01A-01W-0545-08) from TCGA case TCGA-24-1423, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.0 years (22,281 days).
Specimen TCGA-24-1423-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e838e42-bc4f-4262-b928-db6807846c5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1423-10A (Blood Derived Normal), aliquot TCGA-24-1423-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f842391c-2b70-482c-9c75-c23312f636ba

The open-access MAF lists 90 somatic variants for this specimen: 67 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 3, RNA 2, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 158/290 reads (54%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- ACTL6B | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV50517672; called by muse, mutect2, varscan2
- ADCY2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 191/602 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs144846733; called by muse, mutect2, varscan2
- ATG9B | c.2154G>T p.W718C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52494510; called by muse, mutect2, varscan2
- ATP13A1 | c.1499C>A p.A500D | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52290524, COSV99365996; called by muse, mutect2, varscan2
- B4GALNT4 | c.3056A>G p.Y1019C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100327311; called by muse, mutect2, varscan2
- CBLB | c.2277C>G p.D759E | Missense Mutation (SNP) | VAF 121/255 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51434815; called by muse, mutect2, varscan2
- CDK17 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as COSV54132659; called by muse, mutect2, varscan2
- CEP72 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53796471; called by muse, mutect2, varscan2
- CFAP45 | c.315C>G p.S105R | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.855); catalogued as COSV63650336, COSV63650568; called by muse, mutect2, varscan2
- CHD2 | c.4769C>G p.S1590C | Missense Mutation (SNP) | VAF 215/393 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV101244632, COSV67708334; called by muse, mutect2, varscan2
- CSF3R | c.1089A>T p.E363D | Missense Mutation (SNP) | VAF 252/695 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV58970829; called by muse, mutect2, varscan2
- EMC2 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs1358257642, COSV55210942; called by muse, mutect2, varscan2
- EPC1 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.949); catalogued as COSV53929134; called by muse, mutect2, varscan2
- FAAH2 | c.275+2T>G p.X92_splice | Splice Site (SNP) | VAF 94/250 reads (38%) | catalogued as COSV66510864; called by muse, mutect2, varscan2
- FBXL19 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs900991417, COSV57942099; called by muse, mutect2, varscan2
- FBXO40 | c.2032C>A p.P678T | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57526863; called by muse, mutect2, varscan2
- FLT1 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 28/887 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99150932; called by muse, mutect2
- GH2 | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 98/1133 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as COSV60427641; called by muse, mutect2
- GOLGA3 | c.773A>C p.N258T | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as COSV52641137; called by muse, mutect2, varscan2
- GPR179 | c.1163G>C p.C388S (on ENST00000621958; = p.C387S on NM_001004334.4) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as rs777594501; called by muse, mutect2, varscan2
- IGFN1 | c.1430G>T p.C477F (on ENST00000295591 / NM_001367841.1; = p.C2934F on NM_001164586.2) | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55182280; called by muse, mutect2, varscan2
- INKA1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs144945954; called by muse, mutect2, varscan2
- ITIH1 | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 35/500 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99835082, COSV99835237; called by muse, mutect2
- JMJD1C | c.7295A>G p.N2432S | Missense Mutation (SNP) | VAF 172/555 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.08); catalogued as COSV59517416; called by muse, mutect2, varscan2
- KATNBL1 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 95/118 reads (81%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV56625208; called by muse, mutect2, varscan2
- KRT6B | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52886001; called by muse, mutect2, varscan2
- MARF1 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 11/297 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as COSV100705705; called by muse, mutect2
- MDH2 | c.920A>G p.K307R | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); catalogued as rs781994282, COSV59885116; called by muse, mutect2, varscan2
- MED23 | c.2779-1G>C p.X927_splice | Splice Site (SNP) | VAF 16/46 reads (35%) | catalogued as COSV63436390; called by muse, mutect2, varscan2
- MGAM | c.1559A>T p.Q520L | Missense Mutation (SNP) | VAF 350/930 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV72075426; called by muse, mutect2, varscan2
- MRPL58 | c.387G>C p.R129S | Missense Mutation (SNP) | VAF 80/112 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV56901766; called by muse, mutect2, varscan2
- MYT1L | c.2969G>T p.G990V | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101216941; called by muse, mutect2
- NCF2 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 157/848 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as rs778521448, COSV62316516; called by muse, mutect2, varscan2
- NES | c.2716C>G p.P906A | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV63962565; called by muse, mutect2, varscan2
- OPHN1 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62785956; called by muse, mutect2, varscan2
- OSBPL1A | c.1978G>A p.A660T (on ENST00000319481 / NM_080597.4; = p.A147T on NM_018030.4) | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60202595; called by muse, mutect2, varscan2
- OSMR | c.2846T>C p.M949T | Missense Mutation (SNP) | VAF 375/996 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV57090542; called by muse, mutect2, varscan2
- PTPN18 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV51560456; called by muse, mutect2, varscan2
- RAB26 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99269876; called by muse, mutect2, varscan2
- RAB7A | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99413956; called by muse, mutect2
- RELN | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 20/555 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV100632959; called by muse, mutect2
- RFC1 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.168); catalogued as COSV62900824; called by muse, mutect2, varscan2
- RPS6KC1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 123/236 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873784, COSV65297070; called by muse, mutect2, varscan2
- RYR2 | c.5392G>T p.A1798S | Missense Mutation (SNP) | VAF 987/1843 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV63707759; called by muse, mutect2, varscan2
- SOAT2 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56860938; called by muse, mutect2, varscan2
- SRSF11 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 100/142 reads (70%) | catalogued as COSV63937644; called by muse, mutect2, varscan2
- STXBP5L | c.1278T>G p.I426M | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56530548; called by muse, mutect2, varscan2
- SYNJ1 | c.4100T>C p.L1367P | Missense Mutation (SNP) | VAF 111/377 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59155018; called by muse, mutect2, varscan2
- TAB2 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 17/436 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV99644653; called by muse, mutect2
- TBC1D8B | c.2893G>C p.A965P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.355); catalogued as COSV52182555; called by muse, mutect2, varscan2
- TFRC | c.1973C>G p.T658R | Missense Mutation (SNP) | VAF 245/475 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0.025); catalogued as COSV64056120; called by muse, mutect2, varscan2
- TMC3 | c.526A>T p.S176C | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV63924327; called by muse, mutect2, varscan2
- TMPRSS9 | c.532T>G p.L178V (on ENST00000648592; = p.L144V on NM_182973.2) | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV60230664; called by muse, mutect2, varscan2
- TOX3 | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 254/832 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99567243; called by muse, varscan2
- TTN | c.57518G>C p.R19173T (on ENST00000591111; = p.R11749T on NM_003319.4) | Missense Mutation (SNP) | VAF 258/995 reads (26%) | PolyPhen possibly damaging (0.544); catalogued as COSV100607402, COSV60283900; called by muse, mutect2, varscan2
- USP46 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71513133; called by muse, mutect2, varscan2
- WASF2 | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 299/420 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV71006495; called by muse, mutect2, varscan2
- WNT2 | c.86A>T p.Y29F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV99625885; called by muse, mutect2
- ZFC3H1 | c.5091T>G p.I1697M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV66435340; called by muse, mutect2, varscan2
- ZNF592 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 30/539 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.427); catalogued as rs200524575; called by muse, mutect2
- ATP10B | c.1771_1801del p.N591Pfs*28 | Frame Shift Del (DEL) | VAF 34/62 reads (55%) | called by mutect2, pindel
- BRWD3 | c.1029_1042del p.I344Ffs*2 | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | called by mutect2, pindel, varscan2
- KRTAP10-9 | c.123_148del p.C42Efs*13 | Frame Shift Del (DEL) | VAF 18/128 reads (14%) | called by mutect2, pindel
- SNTB1 | c.572-31_578del p.X191_splice | Splice Site (DEL) | VAF 124/699 reads (18%) | called by mutect2, pindel
- SVEP1 | c.9512_9533del p.P3171Lfs*10 | Frame Shift Del (DEL) | VAF 94/352 reads (27%) | called by mutect2, pindel
- TMX1 | c.631dup p.R211Kfs*33 | Frame Shift Ins (INS) | VAF 3/18 reads (17%) | called by pindel, varscan2
- ARID5B | c.3288G>A p.P1096= | Silent (SNP) | VAF 67/206 reads (33%) | catalogued as rs1406865250, COSV54433773; called by muse, mutect2, varscan2
- ASTN1 | c.2901C>T p.A967= | Silent (SNP) | VAF 27/560 reads (5%) | catalogued as COSV100705854, COSV62499741; called by muse, mutect2
- COL6A5 | c.6456G>A p.K2152= (on ENST00000312481; = p.K2148= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV55213434; called by muse, mutect2, varscan2
- DENND1C | c.1470A>C p.S490= | Silent (SNP) | VAF 57/141 reads (40%) | catalogued as COSV100375231; called by muse, mutect2, varscan2
- DUSP5 | c.951C>A p.I317= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as COSV63647122; called by muse, mutect2, varscan2
- HPCA | c.180C>T p.D60= | Silent (SNP) | VAF 499/655 reads (76%) | catalogued as rs555055449, COSV65102815; ClinVar: likely benign; called by muse, mutect2, varscan2
- IER2 | c.78T>G p.G26= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV52848763; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1548C>A p.V516= (on ENST00000439118 / NM_001008949.3; = p.V524= on NM_178495.6) | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV100742168, COSV100742172; called by muse, mutect2
- LRRN2 | c.2019C>A p.G673= | Silent (SNP) | VAF 20/323 reads (6%) | catalogued as COSV100912795; called by muse, mutect2
- NLGN4X | c.1851C>T p.D617= | Silent (SNP) | VAF 219/474 reads (46%) | catalogued as COSV52032968; called by muse, mutect2, varscan2
- NRXN1 | c.2298C>A p.T766= | Silent (SNP) | VAF 96/381 reads (25%) | catalogued as COSV58484573; called by muse, mutect2, varscan2
- SETD1A | c.3282G>T p.V1094= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as COSV52691629; called by muse, mutect2, varscan2
- SLAMF6 | c.867T>C p.T289= (on ENST00000368057 / NM_001184714.2; = p.T288= on NM_052931.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 249/865 reads (29%) | catalogued as COSV100924855; called by muse, mutect2, varscan2
- SPDYE1 | c.702G>C p.G234= | Silent (SNP) | VAF 109/472 reads (23%) | catalogued as COSV51672075; called by muse, mutect2, varscan2
- SSTR2 | c.813C>A p.P271= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV100192011; called by muse, mutect2
- TIAM1 | c.3072C>A p.S1024= | Silent (SNP) | VAF 38/1073 reads (4%) | catalogued as COSV54576214, COSV99733851; called by muse, mutect2
- TRIM37 | c.2316A>G p.L772= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as rs765983264, COSV51883322, COSV99232531; ClinVar: uncertain significance; called by muse, mutect2
- TRIM41 | c.675C>T p.G225= | Silent (SNP) | VAF 99/118 reads (84%) | catalogued as COSV100163044, COSV100163335; called by muse, mutect2, varscan2
- ZEB2 | c.3360G>T p.G1120= | Silent (SNP) | VAF 158/615 reads (26%) | catalogued as COSV57964652; called by muse, mutect2, varscan2
- ZNF536 | c.1923C>T p.R641= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV100834916; called by muse, mutect2, varscan2
- MIR496 | n.22G>T | RNA (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2
- NDUFV3 | c.170-5494A>G | Intron (SNP) | VAF 235/402 reads (58%) | catalogued as COSV61088383; called by muse, mutect2, varscan2
- WASF4P | n.71A>T | RNA (SNP) | VAF 93/402 reads (23%) | called by muse, mutect2, varscan2
